Gene-level copy-number profile of tumor specimen C3L-05644-04 from CPTAC case C3L-05644, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 70.5 years (25,741 days).
Specimen C3L-05644-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f23a27cf-ac8d-40e1-8577-05642be8ea0f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05644-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/0c593aeb-b390-4cfa-889d-a4fc80872ce4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 469; copy number 2: 8,516; copy number 3: 35,516; copy number 4: 4,378; copy number 5: 6,438; copy number 6: 46; copy number 7: 2,959; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–22,455,740, 66 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,960 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,934,776, 26 genes, copy number 7 (within-gene range 5–7): AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1.
- chr2:242,175,181–242,175,634, 1 gene, copy number 7: RPL23AP88.
- chr7:37,032–159,233,377, 2,933 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 469. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
